MMRF case MMRF_2762 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/92c881f0-c3ba-487c-a491-f3df63df7075

Demographics
Sex at birth: male; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.0 years (19,375 days); ISS stage: I; Days to last known disease status: 323 days; Days to last follow up: 323 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -8, day 323.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Platelets 173 ×10⁹/L.
- Calcium 2.22 mmol/L.
- Albumin 44 g/L.
- Beta 2 Microglobulin 3.2 µg/mL.
- Hemoglobin 7.19 mmol/L.
- M Protein 3.83 g/dL.
- Serum Free Immunoglobulin Light Chain, Kappa 3.8 mg/dL.
- Lactate Dehydrogenase 1.9 µkat/L.
- Creatinine 70.7 µmol/L.
- Serum Free Immunoglobulin Light Chain, Lambda 875 mg/dL.
- Absolute Neutrophil 3.62 ×10⁹/L.

Other clinical attributes
- Day -8: Weight: 75 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2762_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_2762_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
